Somatic mutation profile of tumor specimen C3N-01080-03 (aliquot CPT0211320006) from CPTAC case C3N-01080, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Tumor grade: G1.
Specimen C3N-01080-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99df8e51-8810-45c8-b2c8-12cf0d0d6101.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01080-71 (Blood Derived Normal), aliquot CPT0211420002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c690128-1df2-4b4c-a418-9dfd93c6d769

The open-access MAF lists 74 somatic variants for this specimen: 59 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 11, Nonsense Mutation 5, Frame Shift Del 4, Intron 3, Frame Shift Ins 2, Splice Region 2, Splice Site 1, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG3 | c.910G>T p.D304Y | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59650108; called by muse, mutect2, varscan2
- APOL4 | c.227C>T p.A76V (on ENST00000352371 / NM_145660.2; = p.A73V on NM_030643.4) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs757150141; called by mutect2, varscan2
- ATAD2B | c.2852G>A p.R951Q | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.964); catalogued as COSV53206489; called by muse, mutect2
- BAP1 | c.629T>C p.I210T | Missense Mutation (SNP) | VAF 74/459 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1383276496, COSV56243015; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLGN | c.955C>G p.P319A | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); catalogued as COSV57774531; called by muse, mutect2, varscan2
- CNTNAP4 | c.1421C>A p.A474D | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as COSV56680912; called by mutect2, varscan2
- DEUP1 | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | catalogued as COSV99977029; called by muse, mutect2
- EDARADD | c.166G>A p.E56K (on ENST00000334232 / NM_145861.4; = p.E46K on NM_080738.4) | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV100513191; called by muse, mutect2
- EGF | c.3362C>A p.A1121E | Missense Mutation (SNP) | VAF 25/268 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs772594896; called by muse, mutect2
- EXOC3L4 | c.549C>G p.C183W | Missense Mutation (SNP) | VAF 52/371 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs762863415; called by muse, mutect2, varscan2
- KIF4B | c.3187G>A p.D1063N | Missense Mutation (SNP) | VAF 31/326 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs544665418, COSV70530074; called by muse, mutect2, varscan2
- LRP3 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs779980301, COSV99471903; called by muse, mutect2, varscan2
- NRXN3 | c.2840G>A p.R947H (on ENST00000335750 / NM_001330195.2; = p.R574H on NM_004796.6) | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.584); catalogued as rs140528152; called by muse, mutect2, varscan2
- PEG3 | c.128A>C p.E43A | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.201); catalogued as COSV55631553; called by muse, mutect2
- PPP1R13B | c.2443G>A p.E815K | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.137); catalogued as rs765773923, COSV99159058; called by muse, mutect2, varscan2
- TAF1L | c.2672C>T p.T891M | Missense Mutation (SNP) | VAF 30/331 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1183499757, COSV54256582, COSV99645119; called by muse, mutect2
- TSC1 | c.364-1G>A p.X122_splice | Splice Site (SNP) | VAF 37/213 reads (17%) | catalogued as CS982386, COSV53763905, COSV53775762; called by muse, mutect2, varscan2
- ABCC3 | c.2288G>T p.R763L | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD30B | c.3912T>A p.F1304L | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.013); called by muse, varscan2
- ARAP3 | c.4406C>A p.P1469H | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.498); called by muse, mutect2
- ARPC2 | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- ATP1A4 | c.2698T>C p.Y900H | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.014); called by muse, mutect2
- B4GALNT2 | c.201A>T p.R67S | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- BCAR3 | c.634T>C p.Y212H | Missense Mutation (SNP) | VAF 75/440 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- C11orf54 | c.723T>A p.Y241* (on ENST00000331239; = p.Y191* on NM_014039.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2
- CHUK | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/155 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- COL1A1 | c.3261+4del | Splice Region (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel, varscan2
- DCLK1 | c.599C>G p.A200G | Missense Mutation (SNP) | VAF 23/239 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- DPYSL3 | c.876C>A p.S292R | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- EFEMP2 | c.1172A>C p.Q391P | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GHRHR | c.974+7T>A | Splice Region (SNP) | VAF 32/217 reads (15%) | called by muse, mutect2, varscan2
- IGLON5 | c.596A>G p.N199S | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ILF3 | c.1611del p.L539Sfs*47 | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | called by mutect2, pindel, varscan2
- KCNH3 | c.1306A>G p.N436D | Missense Mutation (SNP) | VAF 32/253 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- KMT2C | c.5846T>C p.V1949A | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- LAMA4 | c.3762T>G p.F1254L (on ENST00000230538 / NM_001105206.3; = p.F1247L on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.159); called by muse, mutect2
- MAGEA11 | c.1099A>T p.K367* | Nonsense Mutation (SNP) | VAF 26/91 reads (29%) | called by muse, mutect2, varscan2
- MFSD4A | c.534del p.T179Pfs*18 | Frame Shift Del (DEL) | VAF 51/428 reads (12%) | called by mutect2, pindel, varscan2
- MLLT10 | c.3032T>C p.L1011P | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- MMRN2 | c.2027A>G p.E676G | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- MTMR3 | c.1976A>C p.D659A | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NMT2 | c.1218_1219insA p.S407Ifs*39 | Frame Shift Ins (INS) | VAF 21/178 reads (12%) | called by mutect2, varscan2
- NPC2 | c.325T>C p.Y109H | Missense Mutation (SNP) | VAF 60/378 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- OBSCN | c.11206G>C p.E3736Q | Missense Mutation (SNP) | VAF 26/432 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.673); called by muse, mutect2
- OLFM3 | c.963dup p.V322Sfs*14 (on ENST00000338858 / NM_001288821.1; = p.V302Sfs*14 on NM_058170.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 18/158 reads (11%) | called by mutect2, varscan2
- OR10H3 | c.676G>C p.A226P | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PBRM1 | c.3617C>T p.P1206L (on ENST00000296302 / NM_001366071.2; = p.P1181L on NM_018313.5) | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHB3 | c.380A>G p.N127S | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PLAUR | c.569T>G p.L190R | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLD3 | c.551_552del p.Q184Rfs*19 | Frame Shift Del (DEL) | VAF 37/229 reads (16%) | called by mutect2, pindel, varscan2
- RAB21 | c.644A>G p.Q215R | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SAP130 | c.2807A>T p.Q936L | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ST3GAL4 | c.19T>C p.W7R | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- STAB1 | c.4020C>A p.C1340* | Nonsense Mutation (SNP) | VAF 21/147 reads (14%) | called by muse, mutect2, varscan2
- STIM1 | c.107C>A p.S36* | Nonsense Mutation (SNP) | VAF 25/141 reads (18%) | called by muse, mutect2, varscan2
- SUPT16H | c.2744G>T p.G915V | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- SYTL3 | c.962A>T p.H321L (on ENST00000611299 / NM_001242394.1; = p.H253L on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- TMEM229A | c.634del p.R212Gfs*103 | Frame Shift Del (DEL) | VAF 22/209 reads (11%) | called by pindel, varscan2
- ZNF569 | c.828G>T p.E276D | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- ARHGAP39 | c.813G>A p.R271= | Silent (SNP) | VAF 18/159 reads (11%) | catalogued as rs373128040; called by muse, mutect2, varscan2
- CES3 | c.315C>T p.N105= | Silent (SNP) | VAF 18/122 reads (15%) | catalogued as rs1167024708; called by muse, mutect2, varscan2
- EIPR1 | c.1080G>T p.P360= | Silent (SNP) | VAF 12/189 reads (6%) | catalogued as rs543753999, COSV101182053; called by muse, mutect2
- ENOSF1 | c.33C>A p.V11= | Silent (SNP) | VAF 52/408 reads (13%) | called by muse, varscan2
- HEPACAM2 | c.423G>A p.T141= (on ENST00000394468 / NM_001039372.4; = p.T129= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs370507881; called by muse, mutect2
- IMP3 | c.183C>T p.R61= | Silent (SNP) | VAF 46/293 reads (16%) | called by muse, mutect2, varscan2
- KRT37 | c.144C>T p.N48= | Silent (SNP) | VAF 33/193 reads (17%) | catalogued as rs751933378, COSV56660125; called by muse, mutect2, varscan2
- MCIDAS | c.675G>A p.K225= | Silent (SNP) | VAF 28/187 reads (15%) | called by muse, mutect2, varscan2
- OR1I1 | c.21C>T p.T7= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs201185319; called by muse, mutect2
- TAPBPL | c.1113A>G p.A371= | Silent (SNP) | VAF 54/309 reads (17%) | called by muse, mutect2, varscan2
- ZFPM2 | c.1260T>A p.L420= | Silent (SNP) | VAF 29/400 reads (7%) | called by muse, mutect2
- CHD8 | c.-215-5112T>C | Intron (SNP) | VAF 28/182 reads (15%) | called by muse, mutect2, varscan2
- COL4A2 | c.478-55A>C | Intron (SNP) | VAF 20/127 reads (16%) | called by muse, mutect2, varscan2
- LMNA | c.1157+40T>C | Intron (SNP) | VAF 20/175 reads (11%) | called by muse, mutect2, varscan2
- NAP1L6P | n.380G>T | RNA (SNP) | VAF 16/173 reads (9%) | called by muse, mutect2
